CPTAC case C3L-00810 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0d9a5fb2-066a-44f1-8e85-3bcefd32496c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Dead; Days to death: 396 days (1.1 years); Year of death: 2019; Cause of death: Cancer Related.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 63.8 years (23,309 days); Year of diagnosis: 2018; Days to last known disease status: 396 days (1.1 years); Progression or recurrence: no; Days to last follow up: 361 days.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Stem Cell Transplantation, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 336 days; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 361 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 84.6 kg; Height: 170.9 cm; BMI: 28.97.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 5; Cigarettes per day: 20; Tobacco smoking onset year: 1993; Tobacco smoking quit year: 1998; Exposure duration years: 5.

Biospecimens (5 samples)
- Samples C3L-00810-50, C3L-00810-51, C3L-00810-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-00810-54, C3L-00810-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 3 days; Time between excision and freezing: 390 minutes; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
